Somatic mutation profile of tumor specimen 0DR3MA from CCDI case PBCFPA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 16.0 years (5,834 days).
Specimen 0DR3MA: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4d212bf-0c46-43b4-9a6e-70e7f4d084e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR3L1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a13feb19-e46a-4a44-95d7-cbd477289e68

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZCCHC12 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 206/442 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs369803562, COSV59571753; called by muse, mutect2, varscan2
- PYM1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL17 | c.168C>A p.A56= | Silent (SNP) | VAF 16/221 reads (7%) | catalogued as rs553999710; called by muse, mutect2
- KRTAP10-12 | c.186C>T p.C62= | Silent (SNP) | VAF 74/370 reads (20%) | catalogued as rs1555950790, COSV100551737; called by muse, mutect2, varscan2
- OR2J3 | c.426T>G p.R142= | Silent (SNP) | VAF 104/412 reads (25%) | called by muse, mutect2
- C15orf40 | c.112-23A>T | Intron (SNP) | VAF 49/136 reads (36%) | called by muse, mutect2, varscan2
